Somatic mutation profile of tumor specimen C3L-08429-02 (aliquot CPT0504850006) from CPTAC case C3L-08429, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 61.5 years (22,471 days).
Specimen C3L-08429-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f743c1c-13c5-4330-9f10-626d0203bd88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08429-31 (Blood Derived Normal), aliquot CPT0504830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66a4a05f-fb6e-4ec2-8fb2-a94a074feea5

The open-access MAF lists 381 somatic variants for this specimen: 285 protein-altering or splice-affecting, 88 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 253, Silent 88, Nonsense Mutation 13, Frame Shift Del 7, In Frame Del 5, Intron 5, Splice Site 4, Splice Region 3, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGI2 | c.1808T>G p.L603R | Missense Mutation (SNP) | VAF 111/495 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV62636665, COSV62664406; called by muse, mutect2, varscan2
- ABCA5 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 176/339 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746299297, COSV67017158; called by muse, mutect2, varscan2
- ABCC9 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.71); catalogued as rs1342458654; called by muse, mutect2, varscan2
- AKIRIN1 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.34); catalogued as rs746487361; called by muse, mutect2
- ALOX12 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 139/497 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs1371165523; called by muse, mutect2, varscan2
- AMDHD1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 114/394 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs781422816, COSV99900145; called by muse, varscan2
- APOB | c.3998G>T p.R1333L | Missense Mutation (SNP) | VAF 132/440 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.182); catalogued as COSV51945348; called by muse, mutect2, varscan2
- AR | c.2440T>A p.F814I | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV101017553, COSV65954499; called by muse, mutect2, varscan2
- ARHGAP1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs1295890068, COSV61735763; called by muse, mutect2, varscan2
- B3GNT2 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 91/370 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as rs780891543, COSV57344829; called by muse, mutect2, varscan2
- BATF | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 163/539 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs145411258, COSV54375292; called by muse, mutect2, varscan2
- C19orf54 | c.443G>C p.S148T | Missense Mutation (SNP) | VAF 76/836 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.058); catalogued as rs781016936; called by muse, mutect2
- C2CD3 | c.993G>A p.M331I | Missense Mutation (SNP) | VAF 41/508 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs768465661; called by muse, mutect2
- CAPN12 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 45/684 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.32); catalogued as rs781673043, COSV61016954; called by muse, mutect2
- CASK | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.586); catalogued as rs139731261; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- CATSPER2 | c.701T>C p.L234P | Missense Mutation (SNP) | VAF 55/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1227091715; called by muse, mutect2, varscan2
- CDC14A | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 48/150 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.545); catalogued as rs371468460, COSV100325925; called by muse, mutect2, varscan2
- CDS1 | c.1034A>G p.E345G | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.216); catalogued as rs754964105; called by muse, mutect2
- CEP126 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 58/171 reads (34%) | catalogued as rs374091656; called by muse, mutect2, varscan2
- CHORDC1 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV57706072; called by muse, mutect2, varscan2
- CKAP5 | c.2530G>T p.G844W | Missense Mutation (SNP) | VAF 64/310 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100371481; called by muse, mutect2, varscan2
- CNKSR3 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 19/273 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs757213208; called by muse, mutect2
- DCDC1 | c.3319C>T p.R1107* (on ENST00000597505 / NM_001367979.1; = p.R214* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 82/256 reads (32%) | catalogued as rs975633722, COSV60306647; called by muse, mutect2, varscan2
- DDIT3 | c.-32-7C>G | Splice Region (SNP) | VAF 78/271 reads (29%) | catalogued as COSV56257417; called by muse, mutect2, varscan2
- DDX23 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57284398; called by muse, mutect2, varscan2
- DLGAP2 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 74/688 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as rs371264718; called by muse, mutect2, varscan2
- DNAH6 | c.5116C>A p.P1706T | Missense Mutation (SNP) | VAF 33/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52864994; called by muse, mutect2
- DNHD1 | c.13019C>T p.T4340I | Missense Mutation (SNP) | VAF 108/418 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs916629638; called by muse, mutect2, varscan2
- DOP1B | c.4945G>A p.D1649N | Missense Mutation (SNP) | VAF 129/323 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); catalogued as rs760453207, COSV67693353; called by muse, mutect2, varscan2
- DSG4 | c.2465G>C p.S822T | Missense Mutation (SNP) | VAF 74/362 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57398695; called by muse, mutect2, varscan2
- EIF2AK1 | c.737G>C p.R246T | Missense Mutation (SNP) | VAF 50/407 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV99552426; called by muse, mutect2, varscan2
- EPHA8 | c.662C>A p.A221D | Missense Mutation (SNP) | VAF 88/412 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51274176; called by muse, mutect2, varscan2
- F13A1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 45/496 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as rs760607637; called by muse, mutect2
- FNBP1 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 104/397 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs1175557567, COSV63085035; called by muse, mutect2, varscan2
- FOXD4L4 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 157/1838 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.585); catalogued as rs1458300125; called by muse, mutect2
- FOXD4L5 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 45/393 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.585); catalogued as rs746146813, COSV101073014; called by muse, mutect2, varscan2
- GABBR2 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 93/506 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1395183088; called by muse, mutect2, varscan2
- GABRA1 | c.556A>C p.S186R | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50108312, COSV99195806; called by muse, mutect2, varscan2
- GNAL | c.1043C>T p.P348L (on ENST00000269162 / NM_001142339.3; = p.P425L on NM_182978.4) | Missense Mutation (SNP) | VAF 158/421 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs756685510, COSV99302908; called by muse, mutect2, varscan2
- GPRC6A | c.967G>T p.V323F | Missense Mutation (SNP) | VAF 93/284 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100114801; called by muse, mutect2, varscan2
- GRM7 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 252/601 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as COSV63144426; called by muse, mutect2, varscan2
- HGD | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs569846003, CM115224; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IFT172 | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 84/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750783565, COSV53139101; called by muse, mutect2, varscan2
- KLHL26 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 56/399 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as rs750156278; called by muse, mutect2, varscan2
- KMT2D | c.15781C>G p.Q5261E | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV56489777; called by muse, mutect2, varscan2
- KMT2E | c.2621G>A p.R874Q | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV57569165; called by muse, mutect2, varscan2
- KRT6B | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 56/519 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as rs756538750, COSV52881720; called by muse, mutect2, varscan2
- LAMB4 | c.4480G>A p.V1494M | Missense Mutation (SNP) | VAF 84/337 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs773058475, COSV52716821, COSV99224244; called by muse, mutect2, varscan2
- LAMP1 | c.67A>G p.M23V | Missense Mutation (SNP) | VAF 57/397 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs1039533115; called by muse, mutect2, varscan2
- LRP3 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 95/833 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.012); catalogued as rs751030215; called by muse, mutect2, varscan2
- LRRC23 | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 117/413 reads (28%) | catalogued as COSV50387747; called by muse, mutect2, varscan2
- LRRC30 | c.336A>C p.E112D | Missense Mutation (SNP) | VAF 131/496 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV101274375; called by muse, mutect2, varscan2
- MAP1B | c.6241G>A p.D2081N | Missense Mutation (SNP) | VAF 124/377 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1247833639; called by muse, mutect2, varscan2
- MAP3K21 | c.1553-1G>C p.X518_splice | Splice Site (SNP) | VAF 37/287 reads (13%) | catalogued as COSV100786151; called by muse, mutect2, varscan2
- MAPK9 | c.122+1G>A p.X41_splice | Splice Site (SNP) | VAF 64/211 reads (30%) | catalogued as rs1226139156; called by muse, mutect2, varscan2
- MBD1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 129/484 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.005); catalogued as rs746395056, COSV54002153; called by muse, mutect2, varscan2
- MCC | c.561G>T p.E187D | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100202639; called by muse, mutect2, varscan2
- MEPCE | c.2024A>G p.Q675R | Missense Mutation (SNP) | VAF 102/424 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.419); catalogued as rs1427665929; called by muse, mutect2, varscan2
- MN1 | c.3383G>C p.G1128A | Missense Mutation (SNP) | VAF 84/654 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.64); catalogued as rs935200470; called by muse, mutect2, varscan2
- MORC4 | c.2680C>T p.R894W | Missense Mutation (SNP) | VAF 95/291 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs747662628, COSV55240017; called by muse, mutect2, varscan2
- MPDZ | c.5194C>G p.P1732A | Missense Mutation (SNP) | VAF 42/379 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.53); catalogued as rs200604403, COSV59924306; called by muse, mutect2, varscan2
- MYLK | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 142/641 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as rs775627574, COSV60616048; called by muse, mutect2, varscan2
- MYO1B | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 59/270 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV100269180; called by muse, mutect2, varscan2
- NCOA3 | c.2582C>A p.P861H | Missense Mutation (SNP) | VAF 109/638 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.497); catalogued as rs956318204; called by muse, mutect2, varscan2
- NEBL | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs767732816, COSV101008945; called by muse, mutect2, varscan2
- OAS2 | c.1777C>T p.R593W | Missense Mutation (SNP) | VAF 51/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1039747066, COSV100660152; called by muse, mutect2, varscan2
- OR2G2 | c.686T>G p.L229W | Missense Mutation (SNP) | VAF 39/280 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV60741090; called by muse, mutect2, varscan2
- OR4C15 | c.505A>G p.T169A (on ENST00000314644; = p.T115A on NM_001001920.2) | Missense Mutation (SNP) | VAF 83/421 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV58955103; called by muse, mutect2, varscan2
- P3H3 | c.1796G>A p.R599Q | Missense Mutation (SNP) | VAF 107/276 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs765991342; called by muse, mutect2, varscan2
- PCDHB14 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 70/608 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV53386803, COSV53388667; called by muse, mutect2, varscan2
- PCDHGB2 | c.1922G>A p.R641H | Missense Mutation (SNP) | VAF 110/464 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV54043492; called by muse, mutect2
- PELP1 | c.2362G>A p.V788M | Missense Mutation (SNP) | VAF 121/422 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52589519; called by muse, mutect2, varscan2
- PEX16 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355804755, COSV53801645; called by muse, mutect2, varscan2
- RAB44 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 267/517 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs765743466; called by muse, mutect2, varscan2
- RANBP17 | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 30/250 reads (12%) | catalogued as rs201226375, COSV66656014; called by muse, mutect2, varscan2
- RFC1 | c.3269C>T p.S1090F (on ENST00000381897 / NM_001363496.2; = p.S1089F on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/411 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs747464005; called by muse, mutect2, varscan2
- RFC4 | c.938T>C p.V313A | Missense Mutation (SNP) | VAF 110/371 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56216468; called by muse, mutect2, varscan2
- ROBO2 | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371373671; called by muse, mutect2, varscan2
- RPGR | c.2399A>T p.D800V (on ENST00000339363 / NM_001367249.1; = p.D595V on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761787495; called by muse, mutect2
- SAMD3 | c.662G>A p.W221* | Nonsense Mutation (SNP) | VAF 63/207 reads (30%) | catalogued as rs147217519, COSV63718311; called by muse, mutect2, varscan2
- SCFD2 | c.1651C>T p.R551W | Missense Mutation (SNP) | VAF 147/315 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1005696381; called by muse, mutect2, varscan2
- SCN10A | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs553913580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA4D | c.1828C>G p.L610V | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.664); catalogued as rs1206891675, COSV100358826; called by muse, mutect2
- SH3GL2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180303494, COSV66047769, COSV66055997; called by muse, mutect2, varscan2
- SLC43A2 | c.1528C>G p.L510V | Missense Mutation (SNP) | VAF 106/395 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1220268471; called by muse, mutect2, varscan2
- SLC4A11 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 92/350 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777948446; called by muse, mutect2, varscan2
- SORCS1 | c.3267C>T p.A1089= | Splice Region (SNP) | VAF 55/253 reads (22%) | catalogued as COSV53857380, COSV99543460; called by muse, mutect2, varscan2
- SPRED3 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 48/796 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV100612755; called by muse, mutect2
- SPTBN4 | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 86/868 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs1158111299, COSV100150356, COSV58955397; called by muse, mutect2, varscan2
- STAB2 | c.4673T>C p.V1558A | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs755513939; called by muse, mutect2, varscan2
- SYN1 | c.187C>A p.P63T | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV99901253; called by muse, mutect2, varscan2
- SYN2 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 84/364 reads (23%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.57); catalogued as rs557997917; called by muse, mutect2, varscan2
- TAT | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 80/428 reads (19%) | catalogued as rs374271496, COSV100587491; called by muse, mutect2, varscan2
- THSD7A | c.3758G>A p.R1253Q | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.791); catalogued as rs375611920; called by muse, mutect2
- TLR6 | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 112/334 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs1393806742; called by muse, mutect2, varscan2
- TMEM132B | c.2545A>T p.T849S | Missense Mutation (SNP) | VAF 156/460 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.025); catalogued as COSV100170633, COSV54745212; called by muse, mutect2, varscan2
- TRIM42 | c.1987A>C p.N663H | Missense Mutation (SNP) | VAF 94/428 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV53880034; called by muse, mutect2, varscan2
- TTC28 | c.1714C>T p.R572W | Missense Mutation (SNP) | VAF 107/481 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67422058; called by muse, mutect2, varscan2
- TTN | c.93450G>T p.R31150S (on ENST00000591111; = p.R23726S on NM_003319.4) | Missense Mutation (SNP) | VAF 46/386 reads (12%) | PolyPhen benign (0.033); catalogued as COSV60363574; called by muse, mutect2, varscan2
- VCX3A | c.62A>C p.K21T | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as rs1203324384; called by muse, mutect2, varscan2
- VPS8 | c.750C>G p.I250M (on ENST00000625842 / NM_001349294.1; = p.I248M on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/384 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV54993496; called by muse, mutect2, varscan2
- ZFHX4 | c.932A>G p.K311R | Missense Mutation (SNP) | VAF 37/542 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV50485723; called by muse, mutect2
- ZFPM2 | c.2516A>C p.Q839P | Missense Mutation (SNP) | VAF 42/570 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65874002; called by muse, mutect2
- ZHX2 | c.1350G>C p.Q450H | Missense Mutation (SNP) | VAF 91/771 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100072791; called by muse, mutect2, varscan2
- ABCA1 | c.5369T>G p.L1790R | Missense Mutation (SNP) | VAF 133/324 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ACO2 | c.1658G>C p.G553A | Missense Mutation (SNP) | VAF 135/495 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACOT4 | c.778A>C p.S260R | Missense Mutation (SNP) | VAF 127/456 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ACTR2 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 86/270 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- ADAM28 | c.359G>T p.S120I | Missense Mutation (SNP) | VAF 38/263 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS17 | c.1115A>C p.K372T | Missense Mutation (SNP) | VAF 94/329 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- ADRB1 | c.835C>A p.P279T | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, varscan2
- AGAP2 | c.3311_3321del p.V1104Afs*14 (on ENST00000547588 / NM_001122772.2; = p.V748Afs*14 on NM_014770.4) | Frame Shift Del (DEL) | VAF 119/461 reads (26%) | called by mutect2, pindel, varscan2
- ALPK3 | c.1619T>C p.L540S | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AMFR | c.1765C>T p.L589F | Missense Mutation (SNP) | VAF 112/382 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- AMPD1 | c.1609A>G p.K537E | Missense Mutation (SNP) | VAF 59/161 reads (37%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- AMZ1 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 155/563 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ANKRD28 | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- ANKS1A | c.1558_1562del p.L520Yfs*61 | Frame Shift Del (DEL) | VAF 62/515 reads (12%) | called by mutect2, pindel, varscan2
- ANO7 | c.1422G>C p.M474I (on ENST00000274979; = p.M420I on NM_001370694.2) | Missense Mutation (SNP) | VAF 172/585 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- APOB | c.2429C>A p.P810H | Missense Mutation (SNP) | VAF 92/423 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ARHGEF18 | c.2443G>C p.E815Q (on ENST00000359920 / NM_001130955.2; = p.E711Q on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/537 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASNS | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ASXL3 | c.4112C>A p.S1371Y | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- BACE2 | c.1201T>C p.S401P | Missense Mutation (SNP) | VAF 141/321 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAZ2A | c.1393G>A p.V465I | Missense Mutation (SNP) | VAF 74/402 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BCL11B | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 70/312 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- BHLHE22 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 154/511 reads (30%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.046); called by muse, varscan2
- BPI | c.1348G>C p.E450Q (on ENST00000262865; = p.E446Q on NM_001725.3) | Missense Mutation (SNP) | VAF 87/566 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- C12orf42 | c.367A>C p.S123R | Missense Mutation (SNP) | VAF 53/352 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- C1orf127 | c.6G>C p.W2C | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- CAMTA2 | c.3586C>A p.P1196T | Missense Mutation (SNP) | VAF 66/443 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- CAPN11 | c.970del p.R324Gfs*43 | Frame Shift Del (DEL) | VAF 40/410 reads (10%) | called by mutect2, varscan2
- CATSPERG | c.1396_1409del p.G466Hfs*13 | Frame Shift Del (DEL) | VAF 66/452 reads (15%) | called by mutect2, pindel, varscan2
- CCDC168 | c.18716A>C p.K6239T | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- CCDC168 | c.12350T>G p.L4117R | Missense Mutation (SNP) | VAF 86/479 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CD55 | c.888_905del p.Q297_V302del | In Frame Del (DEL) | VAF 107/253 reads (42%) | called by mutect2, pindel, varscan2
- CDK7 | c.650C>G p.S217* | Nonsense Mutation (SNP) | VAF 84/267 reads (31%) | called by muse, mutect2, varscan2
- CDR2 | c.1207T>C p.W403R | Missense Mutation (SNP) | VAF 145/569 reads (25%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- CERS3 | c.71A>G p.D24G | Missense Mutation (SNP) | VAF 43/299 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- CHD5 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 110/275 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- CNTRL | c.2437G>T p.V813L | Missense Mutation (SNP) | VAF 107/353 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COG5 | c.2114T>C p.L705P (on ENST00000347053 / NM_001379512.1; = p.L726P on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- COL19A1 | c.2999C>T p.P1000L | Missense Mutation (SNP) | VAF 92/416 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL7A1 | c.4363C>G p.P1455A | Missense Mutation (SNP) | VAF 69/435 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COP1 | c.1940G>T p.G647V | Missense Mutation (SNP) | VAF 83/208 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CPNE6 | c.549G>T p.E183D | Missense Mutation (SNP) | VAF 49/343 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTDSP2 | c.156G>C p.Q52H | Missense Mutation (SNP) | VAF 113/343 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CXCL6 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 43/475 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2
- DAPK1 | c.720C>G p.Y240* | Nonsense Mutation (SNP) | VAF 86/376 reads (23%) | called by muse, mutect2, varscan2
- DDX46 | c.2941G>C p.E981Q | Missense Mutation (SNP) | VAF 83/283 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- DENND2C | c.917A>G p.E306G | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- DMBT1 | c.4864T>A p.W1622R (on ENST00000338354 / NM_001377530.1; = p.W865R on NM_004406.3) | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- DNAH8 | c.10099T>A p.W3367R | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DOP1B | c.5801T>A p.F1934Y | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DRC1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DRD2 | c.54G>C p.W18C | Missense Mutation (SNP) | VAF 63/376 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.810G>C p.Q270H | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ECHDC1 | c.679G>A p.G227R (on ENST00000531967 / NM_001139510.1; = p.G221R on NM_001002030.2) | Missense Mutation (SNP) | VAF 52/362 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELMO2 | c.173A>T p.Q58L | Missense Mutation (SNP) | VAF 52/608 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.147); called by muse, mutect2
- ELMO3 | c.369G>C p.K123N (on ENST00000652269; = p.K70N on NM_024712.5) | Missense Mutation (SNP) | VAF 65/551 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ENO4 | c.1546A>G p.S516G (on ENST00000622726; = p.S513G on NM_001242699.2) | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- EP300 | c.3463_3486del p.P1155_Y1162del | In Frame Del (DEL) | VAF 54/312 reads (17%) | called by mutect2, pindel, varscan2
- EVI5L | c.2158G>A p.G720R | Missense Mutation (SNP) | VAF 114/446 reads (26%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM47A | c.1721A>C p.K574T | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- FAT3 | c.1435G>T p.A479S | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT4 | c.13640A>T p.E4547V | Missense Mutation (SNP) | VAF 96/336 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FKBP9 | c.811T>G p.C271G | Missense Mutation (SNP) | VAF 101/369 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- FREM2 | c.1400A>C p.N467T | Missense Mutation (SNP) | VAF 145/470 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- FSIP2 | c.4970A>T p.E1657V | Missense Mutation (SNP) | VAF 19/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- FTO | c.1368C>A p.C456* | Nonsense Mutation (SNP) | VAF 84/238 reads (35%) | called by muse, mutect2, varscan2
- GALNT16 | c.1039T>G p.F347V | Missense Mutation (SNP) | VAF 127/419 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GARRE1 | c.2965A>C p.S989R | Missense Mutation (SNP) | VAF 100/1016 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.159); called by muse, mutect2
- GASK1A | c.1706T>G p.L569R | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- GON4L | c.2041C>G p.L681V | Missense Mutation (SNP) | VAF 96/362 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GPR12 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 118/390 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GPR42 | c.489G>C p.Q163H | Missense Mutation (SNP) | VAF 188/323 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GRIN2A | c.1760A>T p.N587I | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- GRM6 | c.2527A>G p.I843V | Missense Mutation (SNP) | VAF 55/351 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- HCN1 | c.2195A>C p.Q732P | Missense Mutation (SNP) | VAF 122/546 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HDGFL2 | c.1958del p.D653Afs*75 (on ENST00000616600 / NM_001001520.3; = p.D652Afs*75 on NM_032631.4) | Frame Shift Del (DEL) | VAF 62/501 reads (12%) | called by mutect2, pindel, varscan2
- HNRNPA1 | c.748G>C p.D250H | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IFNL4 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 76/959 reads (8%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2
- IGHG4 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL17RE | c.1922G>T p.G641V | Missense Mutation (SNP) | VAF 88/703 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IQCA1 | c.2199C>G p.C733W | Missense Mutation (SNP) | VAF 114/412 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- IRF2BP1 | c.1595G>C p.R532P | Missense Mutation (SNP) | VAF 79/541 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGB3 | c.1240G>C p.G414R | Missense Mutation (SNP) | VAF 82/606 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR2 | c.2729T>G p.F910C | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- JOSD1 | c.540G>C p.K180N | Missense Mutation (SNP) | VAF 78/365 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNT1 | c.2761C>A p.L921M (on ENST00000488444; = p.L940M on NM_020822.3) | Missense Mutation (SNP) | VAF 77/381 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- KDM3A | c.3228G>T p.R1076S | Missense Mutation (SNP) | VAF 114/391 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- LAMC1 | c.2158C>A p.P720T | Missense Mutation (SNP) | VAF 191/344 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LINGO1 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 175/541 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LINGO2 | c.450A>C p.Q150H | Missense Mutation (SNP) | VAF 105/383 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- LVRN | c.1724G>T p.G575V | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGED1 | c.301A>G p.K101E | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MARCHF10 | c.2423T>C p.V808A | Missense Mutation (SNP) | VAF 201/360 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MC3R | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 73/508 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED30 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 32/502 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- MID2 | c.1023A>C p.K341N | Missense Mutation (SNP) | VAF 120/215 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- MINAR1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 69/380 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MRPL43 | c.48C>G p.H16Q | Missense Mutation (SNP) | VAF 113/460 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MUC12 | c.13004A>C p.Y4335S (on ENST00000379442; = p.Y4192S on NM_001164462.1) | Missense Mutation (SNP) | VAF 137/542 reads (25%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MYADML2 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 95/514 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- MYH2 | c.3143A>C p.K1048T | Missense Mutation (SNP) | VAF 53/281 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- NAP1L3 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- NAPRT | c.928C>G p.L310V | Missense Mutation (SNP) | VAF 488/815 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NFKBIA | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 59/235 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- NRXN2 | c.3849C>T p.G1283= | Splice Region (SNP) | VAF 26/296 reads (9%) | called by muse, mutect2
- NUP210 | c.5300C>A p.T1767N | Missense Mutation (SNP) | VAF 154/576 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR6C1 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- OTUD1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 147/543 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1087C>A p.P363T (on ENST00000374531 / NM_001037293.2; = p.P395T on NM_053016.6) | Missense Mutation (SNP) | VAF 25/510 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- PCDHA6 | c.2212A>T p.T738S | Missense Mutation (SNP) | VAF 70/415 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PCDHGA10 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 39/310 reads (13%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE6A | c.1903G>T p.G635C | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PEG3 | c.3321T>G p.Y1107* | Nonsense Mutation (SNP) | VAF 50/317 reads (16%) | called by muse, mutect2, varscan2
- PHF12 | c.244T>C p.C82R | Missense Mutation (SNP) | VAF 38/434 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- PHKB | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 83/286 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- PKHD1 | c.9310T>G p.F3104V | Missense Mutation (SNP) | VAF 100/426 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PKP2 | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 89/263 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PLEKHM3 | c.1971_1983del p.P658Rfs*80 | Frame Shift Del (DEL) | VAF 76/253 reads (30%) | called by mutect2, pindel, varscan2
- PPRC1 | c.4478C>A p.S1493* | Nonsense Mutation (SNP) | VAF 101/406 reads (25%) | called by muse, mutect2, varscan2
- PRMT7 | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRTG | c.707_709del p.T236del | In Frame Del (DEL) | VAF 64/188 reads (34%) | called by pindel, varscan2
- PSMD3 | c.1172C>G p.T391S | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PTGIS | c.906T>G p.N302K | Missense Mutation (SNP) | VAF 85/634 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- PTPRQ | c.2015A>G p.K672R (on ENST00000616559; = p.K630R on NM_001145026.2) | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.295); called by muse, mutect2
- RAF1 | c.430A>C p.K144Q | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RASEF | c.1413T>G p.F471L | Missense Mutation (SNP) | VAF 43/338 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM25 | c.1771C>G p.Q591E | Missense Mutation (SNP) | VAF 102/397 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.1916T>G p.L639R | Missense Mutation (SNP) | VAF 46/328 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- RHOJ | c.227C>A p.T76N | Missense Mutation (SNP) | VAF 55/318 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ROBO4 | c.1784C>T p.A595V | Missense Mutation (SNP) | VAF 216/458 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- RYR2 | c.3383T>G p.L1128R | Missense Mutation (SNP) | VAF 119/303 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- RYR3 | c.5764T>G p.S1922A | Missense Mutation (SNP) | VAF 72/307 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- SACS | c.11902_11943del p.K3968_Q3981del | In Frame Del (DEL) | VAF 46/463 reads (10%) | called by mutect2, pindel
- SAP130 | c.878T>A p.V293D | Missense Mutation (SNP) | VAF 117/391 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SDK1 | c.3494T>C p.V1165A | Missense Mutation (SNP) | VAF 77/467 reads (16%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- SFSWAP | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 148/605 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SH3BP2 | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 176/556 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- SLC34A3 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 230/576 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC44A2 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 75/305 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- SLC5A7 | c.1330T>G p.F444V | Missense Mutation (SNP) | VAF 114/523 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO2A1 | c.1288C>G p.P430A | Missense Mutation (SNP) | VAF 43/385 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SLCO4C1 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 28/179 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SNX20 | c.145_156del p.L49_N52del | In Frame Del (DEL) | VAF 110/386 reads (28%) | called by mutect2, pindel, varscan2
- SNX6 | c.597C>A p.F199L (on ENST00000652385; = p.F71L on NM_021249.5) | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SPATA31A3 | c.3663G>A p.M1221I | Missense Mutation (SNP) | VAF 163/564 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ST14 | c.1355-17_1356del p.X452_splice | Splice Site (DEL) | VAF 40/318 reads (13%) | called by mutect2, pindel, varscan2
- SULF1 | c.2156A>C p.N719T | Missense Mutation (SNP) | VAF 237/442 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAF11L13 | c.119G>T p.R40M | Missense Mutation (SNP) | VAF 81/408 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- TAOK1 | c.1541T>G p.L514R | Missense Mutation (SNP) | VAF 76/317 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TBL3 | c.2030A>G p.D677G | Missense Mutation (SNP) | VAF 153/368 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- TDRD15 | c.1946A>T p.N649I | Missense Mutation (SNP) | VAF 67/238 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- TM2D3 | c.327+1G>T p.X109_splice (on ENST00000333202 / NM_078474.3; = p.X83_splice on NM_025141.3) | Splice Site (SNP) | VAF 45/173 reads (26%) | called by muse, mutect2, varscan2
- TMEM245 | c.258G>T p.W86C | Missense Mutation (SNP) | VAF 84/682 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TRAT1 | c.157G>T p.D53Y | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TRAV12-2 | c.84T>G p.N28K | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- TRIM68 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 74/503 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIO | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 100/483 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- TSC1 | c.3212C>G p.S1071C | Missense Mutation (SNP) | VAF 176/480 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, varscan2
- TUB | c.584G>C p.S195T (on ENST00000299506 / NM_177972.3; = p.S250T on NM_003320.4) | Missense Mutation (SNP) | VAF 42/296 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TXK | c.421A>C p.K141Q | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- UBAP1L | c.1091T>A p.V364D | Missense Mutation (SNP) | VAF 70/477 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- UBR5 | c.4219A>G p.K1407E | Missense Mutation (SNP) | VAF 35/362 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- UNC45B | c.1505T>A p.F502Y | Missense Mutation (SNP) | VAF 103/377 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- USP32 | c.305T>G p.L102R | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- VWA5B2 | c.1414A>G p.T472A | Missense Mutation (SNP) | VAF 128/592 reads (22%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- WASL | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 164/706 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- WDR87 | c.2602A>C p.S868R | Missense Mutation (SNP) | VAF 56/541 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- XRCC4 | c.293A>T p.E98V | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ZC3H11B | c.2128T>C p.S710P | Missense Mutation (SNP) | VAF 22/842 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.068); called by muse, mutect2
- ZMYND11 | c.1775C>T p.A592V | Missense Mutation (SNP) | VAF 92/320 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.884); called by muse, varscan2
- ZNF536 | c.1979A>T p.E660V | Missense Mutation (SNP) | VAF 70/1100 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2
- ZNF548 | c.963C>A p.S321R | Missense Mutation (SNP) | VAF 116/393 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF572 | c.1404C>G p.Y468* | Nonsense Mutation (SNP) | VAF 40/634 reads (6%) | called by muse, mutect2
- ZNF598 | c.2441T>C p.L814P | Missense Mutation (SNP) | VAF 48/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF613 | c.1451_1460del p.Y484Lfs*55 (on ENST00000293471 / NM_001031721.4; = p.Y448Lfs*55 on NM_024840.4) | Frame Shift Del (DEL) | VAF 112/286 reads (39%) | called by mutect2, pindel, varscan2
- ZNF728 | c.1675A>C p.T559P | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- ZNF728 | c.1674T>A p.H558Q | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- ZNF781 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ZNF835 | c.1387C>T p.Q463* | Nonsense Mutation (SNP) | VAF 102/387 reads (26%) | called by muse, mutect2, varscan2
- ZNF865 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 61/428 reads (14%) | SIFT tolerated (0.38); called by muse, mutect2, varscan2
- ZNF99 | c.964T>A p.F322I | Missense Mutation (SNP) | VAF 128/358 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ABCA13 | c.12507C>T p.A4169= | Silent (SNP) | VAF 56/250 reads (22%) | catalogued as rs765189084; called by muse, mutect2, varscan2
- ADAMTS12 | c.4320A>T p.G1440= | Silent (SNP) | VAF 61/269 reads (23%) | called by muse, mutect2, varscan2
- ADAMTS17 | c.1530C>T p.T510= | Silent (SNP) | VAF 40/273 reads (15%) | catalogued as rs1299861961; called by muse, mutect2, varscan2
- ADGRD1 | c.2121G>A p.S707= | Silent (SNP) | VAF 97/455 reads (21%) | catalogued as rs1445207312; called by muse, mutect2, varscan2
- ADRM1 | c.63G>A p.K21= | Silent (SNP) | VAF 79/917 reads (9%) | catalogued as rs1330629812; called by muse, mutect2
- AHNAK2 | c.4941C>T p.A1647= | Silent (SNP) | VAF 204/550 reads (37%) | catalogued as rs370540872; called by muse, mutect2, varscan2
- ANKRD28 | c.2292C>T p.C764= | Silent (SNP) | VAF 62/261 reads (24%) | called by muse, mutect2, varscan2
- ARHGAP31 | c.1329C>T p.S443= | Silent (SNP) | VAF 240/603 reads (40%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.2418G>A p.A806= (on ENST00000337414 / NM_013427.3; = p.A603= on NM_013423.3) | Silent (SNP) | VAF 231/543 reads (43%) | called by muse, mutect2, varscan2
- ASAH2 | c.1563T>A p.I521= | Silent (SNP) | VAF 115/430 reads (27%) | called by muse, mutect2, varscan2
- ATP11B | c.3415C>A p.R1139= | Silent (SNP) | VAF 79/457 reads (17%) | called by muse, mutect2, varscan2
- AUTS2 | c.2829C>T p.Y943= | Silent (SNP) | VAF 116/507 reads (23%) | catalogued as rs199500874; ClinVar: likely benign; called by muse, mutect2, varscan2
- BACE2 | c.975C>T p.R325= | Silent (SNP) | VAF 71/215 reads (33%) | catalogued as rs764240973, COSV100160717; called by muse, mutect2, varscan2
- BMF | c.348T>A p.I116= | Silent (SNP) | VAF 125/292 reads (43%) | called by muse, mutect2, varscan2
- BRINP2 | c.1776C>A p.P592= | Silent (SNP) | VAF 208/415 reads (50%) | called by muse, mutect2, varscan2
- BTBD8 | c.4107C>A p.V1369= (on ENST00000636805 / NM_001376131.1; = p.V856= on NM_015237.4) | Silent (SNP) | VAF 62/348 reads (18%) | called by muse, mutect2, varscan2
- CACNA1A | c.1230C>T p.D410= | Silent (SNP) | VAF 33/351 reads (9%) | catalogued as rs751952553; ClinVar: likely benign; called by muse, mutect2
- CENPO | c.387T>G p.A129= | Silent (SNP) | VAF 84/250 reads (34%) | called by muse, mutect2, varscan2
- CFAP47 | c.7035A>G p.K2345= | Silent (SNP) | VAF 34/164 reads (21%) | called by muse, mutect2, varscan2
- COBL | c.1818C>T p.D606= | Silent (SNP) | VAF 66/434 reads (15%) | called by muse, mutect2, varscan2
- CYRIA | c.813T>A p.A271= | Silent (SNP) | VAF 59/225 reads (26%) | called by muse, mutect2, varscan2
- DHX38 | c.1596G>C p.L532= | Silent (SNP) | VAF 107/443 reads (24%) | called by muse, mutect2, varscan2
- DIDO1 | c.4968G>C p.R1656= | Silent (SNP) | VAF 157/1006 reads (16%) | catalogued as COSV56623033; called by muse, mutect2, varscan2
- EEF2 | c.2163C>T p.I721= | Silent (SNP) | VAF 36/554 reads (6%) | catalogued as rs1292862933, COSV58580555; called by muse, mutect2
- EFCC1 | c.1647G>A p.R549= | Silent (SNP) | VAF 55/511 reads (11%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.471G>C p.V157= | Silent (SNP) | VAF 82/411 reads (20%) | called by muse, mutect2, varscan2
- EPN2 | c.738C>T p.P246= | Silent (SNP) | VAF 114/455 reads (25%) | catalogued as rs1218942002; called by muse, mutect2, varscan2
- FAM149A | c.2100G>A p.S700= (on ENST00000356371 / NM_001367768.2; = p.S409= on NM_015398.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 91/226 reads (40%) | catalogued as rs373524360; called by muse, mutect2, varscan2
- FAM83C | c.423C>T p.F141= | Silent (SNP) | VAF 92/1062 reads (9%) | called by muse, mutect2
- FBN2 | c.51C>A p.G17= | Silent (SNP) | VAF 130/462 reads (28%) | called by muse, mutect2, varscan2
- FGD6 | c.2916A>G p.E972= | Silent (SNP) | VAF 83/253 reads (33%) | called by muse, mutect2, varscan2
- GRIN3A | c.1608G>A p.L536= | Silent (SNP) | VAF 87/400 reads (22%) | called by muse, mutect2, varscan2
- HGF | c.612T>A p.P204= | Silent (SNP) | VAF 26/284 reads (9%) | called by muse, mutect2
- HIC1 | c.378G>T p.L126= (on ENST00000322941 / NM_001098202.1; = p.L107= on NM_006497.4) | Silent (SNP) | VAF 212/686 reads (31%) | called by muse, varscan2
- KLHL10 | c.15C>T p.S5= | Silent (SNP) | VAF 192/306 reads (63%) | catalogued as rs782716083; called by muse, mutect2, varscan2
- LRP1 | c.1887G>C p.V629= | Silent (SNP) | VAF 121/406 reads (30%) | called by muse, mutect2, varscan2
- LRP1 | c.5286G>A p.G1762= | Silent (SNP) | VAF 68/410 reads (17%) | called by muse, mutect2, varscan2
- LRP1 | c.10317C>T p.C3439= | Silent (SNP) | VAF 48/266 reads (18%) | catalogued as rs1342752312, COSV54504032; called by muse, mutect2
- MADD | c.622C>T p.L208= | Silent (SNP) | VAF 53/241 reads (22%) | catalogued as rs776326962; called by muse, mutect2, varscan2
- MAML2 | c.1614T>C p.S538= | Silent (SNP) | VAF 82/392 reads (21%) | called by muse, mutect2, varscan2
- MED12 | c.5316G>A p.P1772= | Silent (SNP) | VAF 86/322 reads (27%) | catalogued as rs398124199; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC12 | c.201G>T p.G67= | Silent (SNP) | VAF 57/539 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.20133A>G p.P6711= | Silent (SNP) | VAF 114/335 reads (34%) | called by muse, mutect2, varscan2
- MUC16 | c.9492A>T p.L3164= | Silent (SNP) | VAF 71/224 reads (32%) | called by muse, mutect2, varscan2
- MUC17 | c.11244C>G p.P3748= | Silent (SNP) | VAF 91/600 reads (15%) | called by muse, mutect2, varscan2
- NAA60 | c.504A>T p.R168= | Silent (SNP) | VAF 119/315 reads (38%) | called by muse, mutect2, varscan2
- NECTIN3 | c.876T>C p.N292= | Silent (SNP) | VAF 58/331 reads (18%) | called by muse, mutect2, varscan2
- NIPBL | c.2400C>T p.A800= | Silent (SNP) | VAF 49/473 reads (10%) | called by muse, mutect2, varscan2
- NMRK1 | c.84A>G p.P28= | Silent (SNP) | VAF 57/319 reads (18%) | called by muse, mutect2, varscan2
- NPAS3 | c.2082G>A p.P694= (on ENST00000356141 / NM_001164749.2; = p.P662= on NM_022123.3) | Silent (SNP) | VAF 141/591 reads (24%) | called by muse, mutect2, varscan2
- NTSR1 | c.129G>T p.S43= | Silent (SNP) | VAF 203/1149 reads (18%) | called by muse, mutect2, varscan2
- OR10H3 | c.435T>G p.L145= | Silent (SNP) | VAF 79/509 reads (16%) | catalogued as COSV100008439; called by muse, mutect2, varscan2
- OR5AC2 | c.723C>T p.S241= | Silent (SNP) | VAF 54/340 reads (16%) | called by muse, mutect2, varscan2
- OVGP1 | c.78T>C p.C26= | Silent (SNP) | VAF 107/260 reads (41%) | catalogued as COSV63859875; called by muse, mutect2, varscan2
- PATL1 | c.1377C>G p.T459= | Silent (SNP) | VAF 77/248 reads (31%) | called by muse, mutect2, varscan2
- PCDHA3 | c.2004G>A p.S668= | Silent (SNP) | VAF 76/275 reads (28%) | catalogued as rs1187418023, COSV63540363; called by muse, mutect2, varscan2
- PDE6C | c.1506C>G p.R502= | Silent (SNP) | VAF 77/306 reads (25%) | called by muse, mutect2, varscan2
- PLXNA1 | c.2601C>T p.L867= | Silent (SNP) | VAF 105/524 reads (20%) | called by muse, mutect2, varscan2
- PRDM9 | c.1569A>G p.K523= | Silent (SNP) | VAF 77/381 reads (20%) | catalogued as COSV99690395; called by muse, mutect2, varscan2
- RHBDD2 | c.60C>T p.A20= | Silent (SNP) | VAF 84/596 reads (14%) | called by muse, mutect2, varscan2
- RNF103 | c.1560T>G p.L520= | Silent (SNP) | VAF 47/386 reads (12%) | catalogued as rs1340098734, COSV99410293; called by muse, mutect2, varscan2
- RRAGD | c.1137G>A p.K379= | Silent (SNP) | VAF 135/443 reads (30%) | catalogued as rs561504020; called by muse, mutect2, varscan2
- SAP130 | c.879C>A p.V293= | Silent (SNP) | VAF 116/393 reads (30%) | catalogued as COSV52103900; called by muse, mutect2, varscan2
- SASH1 | c.2895C>T p.G965= | Silent (SNP) | VAF 15/410 reads (4%) | called by muse, mutect2
- SHISA6 | c.988C>A p.R330= (on ENST00000409168 / NM_001173461.1; = p.R381= on NM_207386.4) | Silent (SNP) | VAF 32/369 reads (9%) | called by muse, mutect2
- SLC1A1 | c.714T>C p.D238= | Silent (SNP) | VAF 39/727 reads (5%) | catalogued as rs1261428236; called by muse, mutect2
- SLC44A2 | c.135G>T p.V45= | Silent (SNP) | VAF 75/303 reads (25%) | called by muse, mutect2, varscan2
- SNAPC4 | c.1140A>G p.E380= | Silent (SNP) | VAF 88/354 reads (25%) | called by muse, mutect2, varscan2
- SPATC1L | c.642C>T p.G214= (on ENST00000291672 / NM_001142854.2; = p.G60= on NM_032261.5) | Silent (SNP) | VAF 175/318 reads (55%) | catalogued as rs149942349; called by muse, mutect2, varscan2
- SRRM1 | c.339A>G p.Q113= | Silent (SNP) | VAF 104/258 reads (40%) | catalogued as COSV60475762; called by muse, varscan2
- SYNE1 | c.15840G>A p.Q5280= (on ENST00000367255 / NM_182961.4; = p.Q5209= on NM_033071.3) | Silent (SNP) | VAF 87/372 reads (23%) | called by muse, mutect2, varscan2
- TBC1D10C | c.927G>A p.L309= | Silent (SNP) | VAF 66/567 reads (12%) | called by muse, mutect2, varscan2
- TDRD1 | c.1074A>G p.P358= | Silent (SNP) | VAF 63/264 reads (24%) | called by muse, mutect2, varscan2
- TIAM1 | c.1494G>A p.E498= | Silent (SNP) | VAF 54/298 reads (18%) | called by muse, mutect2, varscan2
- TNS3 | c.2142G>A p.E714= | Silent (SNP) | VAF 154/545 reads (28%) | called by muse, mutect2, varscan2
- TSHZ3 | c.288A>G p.E96= | Silent (SNP) | VAF 48/594 reads (8%) | called by muse, mutect2
- TTN | c.19612A>C p.R6538= (on ENST00000591111; = p.R5611= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 148/264 reads (56%) | called by muse, mutect2, varscan2
- TUBB4A | c.1185G>A p.L395= | Silent (SNP) | VAF 188/551 reads (34%) | catalogued as rs776118465; called by muse, mutect2, varscan2
- TUBGCP4 | c.375C>T p.F125= | Silent (SNP) | VAF 81/228 reads (36%) | called by muse, mutect2, varscan2
- TYMP | c.387C>G p.L129= | Silent (SNP) | VAF 116/326 reads (36%) | catalogued as COSV52686687; called by muse, mutect2, varscan2
- UBQLNL | c.924T>C p.S308= | Silent (SNP) | VAF 106/444 reads (24%) | called by muse, mutect2, varscan2
- UBR5 | c.4218G>T p.V1406= | Silent (SNP) | VAF 35/355 reads (10%) | called by muse, mutect2
- WDR87 | c.4707A>G p.Q1569= | Silent (SNP) | VAF 107/611 reads (18%) | called by muse, mutect2, varscan2
- ZDHHC4 | c.1029A>G p.Q343= | Silent (SNP) | VAF 32/239 reads (13%) | called by muse, mutect2, varscan2
- ZFP69 | c.565A>C p.R189= | Silent (SNP) | VAF 56/334 reads (17%) | called by muse, mutect2, varscan2
- ZNF282 | c.903G>C p.R301= | Silent (SNP) | VAF 81/532 reads (15%) | called by muse, varscan2
- ZNF518A | c.1227C>T p.N409= | Silent (SNP) | VAF 86/376 reads (23%) | catalogued as rs1461132209; called by muse, mutect2, varscan2
- ZNF568 | c.387G>A p.A129= | Silent (SNP) | VAF 148/309 reads (48%) | catalogued as rs1354238378, COSV70893646; called by muse, mutect2, varscan2
- BCL11A | c.385+4057C>A | Intron (SNP) | VAF 164/285 reads (58%) | called by muse, mutect2, varscan2
- BET1 | c.201+92C>T | Intron (SNP) | VAF 25/335 reads (7%) | catalogued as rs1480452004, COSV55993170; called by muse, mutect2
- CPLANE1 | c.*5194G>T | 3'UTR (SNP) | VAF 90/407 reads (22%) | catalogued as COSV57058719; called by muse, mutect2, varscan2
- FBRS | chr16:30659888 del GAGGAGGAGCCT | 5'Flank (DEL) | VAF 130/716 reads (18%) | catalogued as rs772435746; called by mutect2, varscan2
- FBXO22 | c.794+15C>G | Intron (SNP) | VAF 82/242 reads (34%) | called by muse, mutect2, varscan2
- MAPK4 | c.547-10275G>T | Intron (SNP) | VAF 26/235 reads (11%) | catalogued as rs936133847; called by muse, mutect2, varscan2
- SLC13A2 | c.232-26C>T | Intron (SNP) | VAF 159/573 reads (28%) | catalogued as rs782443284, COSV58994545; called by muse, mutect2, varscan2
- XIRP2 | c.*1281A>G | 3'UTR (SNP) | VAF 84/317 reads (26%) | called by muse, mutect2, varscan2
